Surgical pathology report (de-identified scan), TCGA case TCGA-YA-A8S7, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Spectrum Health, specimen TCGA-YA-A8S7-01A (Primary Tumor).

[page 1 of 2]
Research Gross Description

male with liver and adrenal masses

KD 0-3
Carcinoma, hepatocellular NOS
817013

Site: Liver 22.0

9/11/14

Research Dx

Liver, right hepatectomy:

Poorly-differentiated malignant neoplasm most consistent with hepatocellular carcinoma, see case summary, see comment.

CASE SUMMARY FOR HEPATOCELLULAR CARCINOMA - RIGHT HEPATECTOMY:

Specimen: Liver, gallbladder, adrenal gland, periportal lymph node.

Procedure: Right hepatectomy, left hepatic core biopsy, cholecystectomy, adrenalectomy, periportal lymph node excisional biopsy.

Tumor size: 12 cm (see gross description).

Tumor focality: Multiple (right lobe, left lobe).

Histologic type: Hepatocellular carcinoma, see comment.

Histologic grade: Grade 3 (poorly-differentiated).

Tumor extension: Tumor confined to liver.

Margins: Negative for tumor.

Parenchymal margin: Negative for tumor.

Distance of invasive carcinoma from closest margin: At least 1 cm from parenchymal resection margin.

Lymphovascular invasion: Not identified.

Perineural invasion: Not identified.

Pathologic staging (pTNM):

Primary tumor (pT): pT3a (m) - Multiple tumors more than 5 cm.

Regional lymph nodes (pN): pN0 - No regional lymph node metastasis.

Number lymph nodes examined: 1.

Number lymph nodes involved: 0.

Distant metastasis (pM): M (not applicable).

Additional pathologic findings: Chronic hepatitis consistent with hepatitis C, inflammatory activity grade 1 (portal chronic inflammation), fibrosis stage 3 (septal fibrosis with architectural distortion). Mild macrovesicular steatosis.

AJCC Staging (7th edition): pT3a(m) pN0 M(not applicable)

Research QC

Tumor:

75% tumor nuclei

25% necrosis

0% normal

Normal:

100% liver

Research Specimen

T1-178 mg, T2- mg, T3- mg, T4- mg

N1-222 mg, N2- mg, N3- mg, N4- mg

Specimen Process Time

Plasma/serum/buffy coat

Cold ischemia start time:

Plasma frozen @

[page 2 of 2]
Serum frozen @
Buffy coat frozen @

Tissue:
Cold ischemia start time:
Formalin fixation start time:
Total cold ischemia time:
Formalin fixation stop time:
Total formalin fixation time
Specimen Weight

Specimen Size

Plasma x 3
Serum x 3
Buffy coat x 1

Cryovials x 8
Normal x 4
Tumor x 4
Metastatic x 0

FFPE x 8
Normal x 4
Tumor x 4
Metastatic x 0
Study

Patient Consent
Yes

Source: NCI Genomic Data Commons file 5032b974-0361-42b2-9f32-2f07efa89839 (TCGA-YA-A8S7.CFF98B7F-C09E-441D-BE5F-48A06036735B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).